Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A199, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A199-06A (Metastatic).

108-0-3

Melanoma, NOS

8720/3 12/14/10 *fw*

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left groin dissection.

Site code: groin, lymph node C77.4

FINAL DIAGNOSIS:

PART 1: LEFT SUPERFICIAL GROIN LYMPH NODE DISSECTION -

- A. METASTATIC MELANOMA IN TEN OUT OF TWELVE LYMPH NODES AND FOCALLY ADJACENT SOFT TISSUE.
- B. ABUNDANT MELANOPHAGES PRESENT IN LYMPH NODE AND SOFT TISSUE.

PART 2: LEFT DEEP GROIN LYMPH NODE DISSECTION -

- A. METASTATIC MELANOMA IN NINE OUT OF NINE LYMPH NODES WITH FOCAL SOFT TISSUE EXTENSION.
- B. ABUNDANT MELANOPHAGES PRESENT IN LYMPH NODE AND SOFT TISSUE.

Source: NCI Genomic Data Commons file 5cdb8787-d0c2-4745-83ab-1a5efe9f374e (TCGA-ER-A199.FAD38303-F164-4868-BBB9-F32EA9C97DF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).